Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5181, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5181-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-5181

Clinical Diagnosis & History:

with left renal mass.

Specimens Submitted:

1: KIDNEY; PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. KIDNEY; PARTIAL

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 4.2 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and is labeled "left partial nephrectomy". It consists of a 5.0 x 3.0 x 2.5 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a 4.2 X 3.0 x 2.5 cm encapsulated well circumscribed yellow-tan mass. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. The perinephric fat is sectioned and appears free of tumor. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor with margin

TF-tumor with perinephric fat

TK-tumor with adjacent renal parenchyma

RS - representative sections of unremarkable renal parenchyma

Summary of Sections:

Part 1: KIDNEY; PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	FSC	1
1	RS	1
3	T	3
1	TF	1
1	TK	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA. MARGIN AT DEEP ASPECT IS BENIGN.
- PERMANENT DIAGNOSIS:

Source: NCI Genomic Data Commons file e9e556ce-95f9-4606-8702-940c31733977 (TCGA-BP-5181.6D5AFAFE-EB00-4CC6-B68F-0883D44188C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).